Somatic mutation profile of tumor specimen MMRF_2688_1_BM_CD138pos (aliquot MMRF_2688_1_BM_CD138pos_T1_KHS5U_L14257) from MMRF case MMRF_2688, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.0 years (19,723 days).
Specimen MMRF_2688_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b2a45f0-1409-41cd-bc83-d1df6ed40a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2688_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2688_1_PB_WBC_C2_KHS5U_L14258; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45939f6-3375-4560-abb8-ad5367690a2f

The open-access MAF lists 94 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 21, Silent 12, Intron 11, 5'UTR 6, Nonsense Mutation 4, 3'Flank 2, Splice Site 1, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 35/64 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAG2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | hotspot (GDC flag); catalogued as COSV54350685, COSV54365974; called by muse, mutect2, varscan2
- CARS1 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99542472; called by muse, mutect2, varscan2
- CCDC66 | c.1511G>A p.R504H (on ENST00000394672 / NM_001353147.1; = p.R470H on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs753262226, COSV58309738; called by muse, mutect2, varscan2
- CHD7 | c.4492A>G p.I1498V | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs776062465; called by muse, mutect2, varscan2
- ERBB4 | c.235-2A>C p.X79_splice | Splice Site (SNP) | VAF 74/191 reads (39%) | catalogued as COSV53515236; called by muse, mutect2, varscan2
- FBXO21 | c.1841C>T p.T614M (on ENST00000330622 / NM_033624.3; = p.T607M on NM_015002.3) | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs779512337, COSV104399502; called by muse, mutect2, varscan2
- FIGN | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs374396460; called by muse, mutect2
- FLG | c.5278G>A p.G1760R | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.997); catalogued as COSV64245182, COSV99056592; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV58565670; called by muse, varscan2
- IGHV1-2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as rs541603173; called by muse, varscan2
- IGKV1-5 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs745347286; called by muse, mutect2
- IGLL5 | c.125T>A p.M42K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs140298238; called by muse, mutect2, varscan2
- IRAK1 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs149773870, COSV64110111; called by muse, mutect2
- LMNA | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs1439261714, COSV61543311; ClinVar: uncertain significance; called by muse, mutect2
- PCLO | c.2951G>T p.G984V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61636699; called by muse, mutect2
- SERPING1 | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as CD921031; called by muse, mutect2, varscan2
- SP140 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as rs143791311; called by muse, mutect2, varscan2
- ZSCAN21 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs373816425, COSV52851028; called by muse, mutect2, varscan2
- BARD1 | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- BCL9 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL21A1 | c.2873A>C p.*958Sext*9 | Nonstop Mutation (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- DHH | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH2 | c.10662G>T p.E3554D | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DSG3 | c.2438T>C p.L813S | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMILIN2 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- HUWE1 | c.6763C>T p.R2255W | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IFIT1B | c.977T>A p.I326K | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IMPG2 | c.3005C>G p.S1002C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAML2 | c.2750G>A p.S917N | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- OR51L1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PROB1 | c.1610C>G p.A537G | Missense Mutation (SNP) | VAF 220/350 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RAB36 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- RCL1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- REG3G | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 111/524 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ROBO2 | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBF2 | c.4489T>G p.L1497V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPAG1 | c.2656T>G p.L886V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, varscan2
- SPAG1 | c.2735T>G p.F912C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, varscan2
- VNN2 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDHD1 | c.3285C>G p.N1095K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZDBF2 | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- A2M | c.1944C>G p.V648= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- CENPF | c.3468G>C p.L1156= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- H1-4 | c.351G>A p.K117= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs376044340, COSV56799955; called by muse, mutect2, varscan2
- IGHA1 | c.999G>T p.A333= | Silent (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- KCTD8 | c.999T>C p.H333= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- MPDZ | c.4455G>A p.E1485= | Silent (SNP) | VAF 32/318 reads (10%) | catalogued as rs915444766, COSV59925659; called by muse, mutect2
- PODN | c.1707C>T p.P569= (on ENST00000395871; = p.P521= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 63/173 reads (36%) | catalogued as rs758940588; called by muse, mutect2, varscan2
- PRPF8 | c.6624C>T p.G2208= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs371715532; called by muse, mutect2
- R3HDM2 | c.1935G>A p.A645= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs756082640; called by muse, mutect2, varscan2
- SKOR2 | c.57C>T p.S19= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as rs376817644; called by muse, mutect2, varscan2
- TFIP11 | c.753G>A p.R251= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- VXN | c.372A>G p.K124= | Silent (SNP) | VAF 101/205 reads (49%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-12041G>A | Intron (SNP) | VAF 72/149 reads (48%) | catalogued as rs778846311; called by muse, mutect2, varscan2
- AR | c.*5792C>T | 3'UTR (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- ASMTL | c.339-86G>A | Intron (SNP) | VAF 17/63 reads (27%) | catalogued as rs1376589433; called by muse, mutect2, varscan2
- CCDC102B | c.1263+28C>T | Intron (SNP) | VAF 15/270 reads (6%) | called by muse, mutect2
- CHM | c.*2005C>T | 3'UTR (SNP) | VAF 31/60 reads (52%) | catalogued as rs1425960313; called by muse, mutect2, varscan2
- CTNNA2 | c.102+35993A>T | Intron (SNP) | VAF 92/168 reads (55%) | called by muse, mutect2, varscan2
- DAG1 | c.*1598T>G | 3'UTR (SNP) | VAF 49/193 reads (25%) | called by muse, mutect2, varscan2
- DLD | c.*644G>A | 3'UTR (SNP) | VAF 11/50 reads (22%) | catalogued as rs909402433; called by muse, mutect2, varscan2
- DPYSL5 | c.*3306C>T | 3'UTR (SNP) | VAF 9/108 reads (8%) | catalogued as rs909663720; called by muse, mutect2
- ELAVL2 | c.-12-2765G>A | Intron (SNP) | VAF 73/557 reads (13%) | catalogued as rs777529292, COSV99805636; called by muse, mutect2, varscan2
- FBXL7 | c.740-1260C>G | Intron (SNP) | VAF 75/222 reads (34%) | catalogued as COSV100309616; called by muse, mutect2, varscan2
- FBXO33 | c.*76A>G | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- GJB2 | c.*424G>A | 3'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as rs1047262422; called by muse, mutect2, varscan2
- GPATCH3 | c.1112-50C>T | Intron (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- GPR52 | c.*102T>G | 3'UTR (SNP) | VAF 5/112 reads (4%) | called by muse, mutect2
- H2BC3 | c.-54A>T | 5'UTR (SNP) | VAF 14/34 reads (41%) | catalogued as rs1437160976; called by muse, mutect2
- HIVEP3 | c.*642A>G | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- IGHV1-2 | c.-26A>G | 5'UTR (SNP) | VAF 48/103 reads (47%) | catalogued as rs782632396; called by muse, varscan2
- IQCH | c.*63del | 3'UTR (DEL) | VAF 20/34 reads (59%) | catalogued as rs921678022; called by mutect2, varscan2
- KCNJ5 | chr11:128920408 G>A | 3'Flank (SNP) | VAF 25/168 reads (15%) | catalogued as rs541373622; called by muse, mutect2, varscan2
- LDLRAD4 | c.-118C>T | 5'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- MCOLN2 | c.1543-27G>A | Intron (SNP) | VAF 16/34 reads (47%) | catalogued as rs747742529; called by muse, mutect2
- MS4A7 | c.*1434G>A | 3'UTR (SNP) | VAF 27/68 reads (40%) | catalogued as rs1160734960; called by muse, mutect2, varscan2
- MTHFR | c.*769A>C | 3'UTR (SNP) | VAF 42/97 reads (43%) | catalogued as rs1348002152; called by muse, mutect2, varscan2
- NDST1 | c.*2912G>C | 3'UTR (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- NF2 | c.1737+1618A>G | Intron (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- ORAI2 | c.*2444_*2451del | 3'UTR (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- OSBPL11 | c.*1527G>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- PBX2 | c.*322C>T | 3'UTR (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*1751G>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- PPARGC1B | c.*6570G>T | 3'UTR (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- PRDM15 | chr21:41800505 A>T | 3'Flank (SNP) | VAF 20/64 reads (31%) | catalogued as rs1036129163; called by mutect2, varscan2
- PRLR | c.*5178C>T | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- RAB11FIP3 | c.-315T>C | 5'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- RPL8 | c.500-333A>C | Intron (SNP) | VAF 16/285 reads (6%) | called by muse, mutect2
- SLC7A10 | c.-13G>A | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.*231C>T | 3'UTR (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3980C>T | 5'UTR (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- TCEA1 | c.232+106A>C | Intron (SNP) | VAF 14/172 reads (8%) | catalogued as rs1241991814; called by muse, mutect2
- ZNF385A | c.*374A>C | 3'UTR (SNP) | VAF 148/337 reads (44%) | called by muse, mutect2, varscan2
